Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5517, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5517-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED] with a previous history of biopsy on [REDACTED] this biopsy reveals: right apex = Gleason grade 3+3 = 6; right base = Gleason grade 3+3 = 6; left apex = Gleason grade 3+3 = 6.

PRE-OP DIAGNOSIS: Prostate cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical retropubic prostatectomy.

FINAL DIAGNOSIS:**PART 1:**

LYMPH NODES, RIGHT PELVIC, EXCISION -

NO EVIDENCE OF NEOPLASIA IN TWO LYMPH NODES EXAMINED (0/2).

PART 2:

LYMPH NODES, LEFT PELVIC, EXCISION -

NO EVIDENCE OF NEOPLASIA IN TWO LYMPH NODES EXAMINED (0/2).

PART 3:

PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. MULTIFOCAL INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE 3 + 3 = 6 WITH MINOR TERTIARY GLEASON GRADE 4 COMPONENT COMPRISING 4% OF THE ENTIRE TUMOR VOLUME EXAMINED.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.4 cm.
- C. THE CARCINOMA INVOLVES 15% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA IS ORGAN CONFINED AND SHOWS NO EVIDENCE OF EXTRACAPSULAR EXTENSION.
- E. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- F. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- G. PERINEURAL INVASION IS IDENTIFIED.
- H. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- I. MULTIFOCAL HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. PATHOLOGIC TNM STAGE: pT2c N0 Mx.
- K. TNM HISTOLOGIC GRADE = G2.
- L. BENIGN PROSTATIC HYPERTROPHY AND CHRONIC INFLAMMATION ARE NOTED.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY PROSTATE TUMORS****CLINICAL DATA:**

INVASIVE CA IDENTIFIED?:

PSA value: 9.6

TUMOR HISTOLOGY:

Yes

PRIMARY GLEASON GRADE:

Adenocarcinoma NOS ✓

SECONDARY GLEASON GRADE:

3

GLEASON SUM SCORE:

3

GLEASON 4/5 PERCENTAGE:

6

WEIGHT OF PROSTATE:

4%

TUMOR SIZE:

56.28gm

LOBE LATERALITY:

Maximum dimension: 1.4 cm

PERCENT OF SPECIMEN INVOLVED BY TUMOR:

Right and Left Lobes

MULTIFOCAL DISEASE:

5 - 25%

HIGH GRADE PIN:

Yes

EXTRAPROSTATIC EXTENSION:

Yes - multifocal

PERINEURAL INVASION:

No

ANGIOLYMPHATIC INVASION:

Yes

SEMINAL VESICLE INVASION:

No

SURGICAL MARGIN INVOLVEMENT:

No

LYMPH NODES EXAMINED:

All surgical margins free of tumor

LYMPH NODES POSITIVE:

4

T STAGE, PATHOLOGIC:

0

N STAGE, PATHOLOGIC:

pT2c

M STAGE, PATHOLOGIC:

pN0

HISTOLOGIC GRADE:

pMX

Comment:

G2, Moderately differentiated

There is a minor Gleason grade 4 component, comprising 4% of the total tumor volume examined.

TCGA-EJ-5517

Source: NCI Genomic Data Commons file 6444d3c5-429d-4a0d-9e1f-21b7a33d031e (TCGA-EJ-5517.67B66178-BD1B-44A8-9A30-762B0FC7C1BA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).